Gene-level copy-number profile of tumor specimen C3N-03929-01 from CPTAC case C3N-03929, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 51.0 years (18,638 days).
Specimen C3N-03929-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18999018-0da7-4557-9d1a-3f22ae8fdbde.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03929-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/b33cd6a5-81f0-4452-8510-2cb1ad3dab0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 2,376; copy number 2: 27,900; copy number 3: 15,628; copy number 4: 10,010; copy number 5: 2,903; copy number 6: 43; copy number 7: 21; copy number 8: 4; copy number 13: 4.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–3): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:63,581,254–63,859,641, 13 genes: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,974 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–42,191,523, 621 genes, copy number 5 (broad region; genes not listed).
- chr5:43,065,176–45,895,970, 38 genes, copy number 6 (within-gene range 4–6): ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:5,526,409–18,027,846, 176 genes, copy number 5 (broad region; genes not listed).
- chr7:62,275,361–63,263,456, 13 genes, copy number 5: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7.
- chr9:12,134–73,865, 5 genes, copy number 6 (within-gene range 3–6): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:61,190,003–61,212,373, 4 genes, copy number 13: SPATA31A7, BX005040.3, BX005040.2, FAM74A4.
- chr9:61,581,813–61,662,690, 4 genes, copy number 8: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:112,393,118–135,075,908, 517 genes, copy number 5 (broad region; genes not listed).
- chr15:22,773,063–23,447,243, 21 genes, copy number 7 (within-gene range 4–7): NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, HERC2P6, GOLGA6L2.
- chr17:39,252,663–83,240,804, 1,559 genes, copy number 5 (broad region; genes not listed).
- chr18:9,310,522–9,615,240, 9 genes, copy number 5: AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1.
- chr19:24,004,358–24,163,425, 7 genes, copy number 5: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
